Gene-level copy-number profile of tumor specimen ALCH-B3FV-TTP1-A from ALCHEMIST case ALCH-B3FV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.9 years (26,256 days).
Specimen ALCH-B3FV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 44908af0-23f2-4107-8bc3-78f6e47f5ccf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3FV-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/3bca6968-6c25-4cfb-8cc8-44c275d13675

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 4,594; copy number 2: 50,978; copy number 3: 2,804; copy number 4: 11; copy number 5: 10.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:681,829–689,271, 1 gene (within-gene range 0–2): SLC49A3.
- chr11:90,282,560–90,284,172, 1 gene (within-gene range 0–2): TUBAP2.
- chr20:63,558,086–63,574,239, 1 gene: HELZ2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,498,767, 5 genes, copy number 5: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1.
- chr1:143,745,249–143,797,108, 5 genes, copy number 5: AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P.

Autosomal genes at a single copy (total copy number 1): 4,594. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
